Somatic mutation profile of tumor specimen MP2PRT-PAPLBU-TMP1-A (aliquot MP2PRT-PAPLBU-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPLBU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.9 years (3,632 days).
Specimen MP2PRT-PAPLBU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c216511b-e742-415d-a2eb-f31446ca5c4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPLBU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPLBU-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/662697aa-d61f-4162-97fa-14e6d41c43b0

The open-access MAF lists 132 somatic variants for this specimen: 94 protein-altering or splice-affecting, 30 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 30, Intron 4, Nonsense Mutation 4, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1, RNA 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 86/276 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 28/190 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 66/283 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGPS | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51560637, COSV51563645; called by muse, mutect2, varscan2
- AMER3 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 123/318 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1200629352, COSV58465055; called by muse, mutect2, varscan2
- BEND4 | c.1060T>G p.C354G | Missense Mutation (SNP) | VAF 17/370 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV72469179; called by muse, mutect2
- CFAP47 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 75/249 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.811); catalogued as COSV52891780, COSV99935511; called by muse, mutect2, varscan2
- CHRDL1 | c.1241C>T p.T414I (on ENST00000372045; = p.T420I on NM_145234.4) | Missense Mutation (SNP) | VAF 108/301 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs1215700145; called by muse, mutect2, varscan2
- CREBBP | c.4613C>T p.P1538L | Missense Mutation (SNP) | VAF 139/350 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM160936, COSV99062786; called by muse, mutect2, varscan2
- DCLK3 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 231/503 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs746230526, COSV69362234; called by muse, mutect2, varscan2
- DLG3 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 174/755 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as rs1220564179; called by muse, mutect2, varscan2
- DST | c.16148G>A p.R5383Q (on ENST00000361203 / NM_001374722.1; = p.R2971Q on NM_015548.5) | Missense Mutation (SNP) | VAF 77/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766153258, COSV99056249; called by muse, mutect2, varscan2
- FAP | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 106/261 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs747747073, COSV51861339; called by muse, mutect2, varscan2
- FASN | c.2795C>T p.S932F | Missense Mutation (SNP) | VAF 91/333 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs146356200; called by muse, mutect2, varscan2
- GRIP2 | c.917G>A p.G306E (on ENST00000619221; = p.G209E on NM_001080423.4) | Missense Mutation (SNP) | VAF 207/455 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as rs938986932; called by muse, mutect2, varscan2
- HCRTR2 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 113/353 reads (32%) | catalogued as rs770310033, COSV63794840; called by muse, mutect2, varscan2
- HECW1 | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 166/406 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as COSV67825541; called by muse, mutect2, varscan2
- HS3ST5 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 152/445 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100451479; called by muse, mutect2, varscan2
- KRT3 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 181/365 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV58815646; called by muse, mutect2, varscan2
- LANCL2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 119/305 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs138563706; called by muse, mutect2, varscan2
- MAGI1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs149211419; called by muse, mutect2, varscan2
- MUC16 | c.42633G>A p.W14211* | Nonsense Mutation (SNP) | VAF 149/354 reads (42%) | catalogued as rs746353572; called by muse, mutect2, varscan2
- MYO5B | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 86/277 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368289471; called by muse, mutect2, varscan2
- NAP1L1 | c.1047T>A p.D349E | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.935); catalogued as COSV99673941; called by muse, mutect2
- NMT1 | c.101A>C p.E34A | Missense Mutation (SNP) | VAF 134/438 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); catalogued as COSV51958320; called by muse, mutect2, varscan2
- OBSL1 | c.3751C>T p.P1251S | Missense Mutation (SNP) | VAF 165/364 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as COSV99216236; called by muse, mutect2, varscan2
- OR4Q2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 133/442 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754729030; called by muse, mutect2, varscan2
- OR8J3 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 117/264 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100041072, COSV56879215, COSV56883780; called by muse, mutect2, varscan2
- PCDHB5 | c.2164G>A p.G722S | Missense Mutation (SNP) | VAF 131/538 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.087); catalogued as rs1372544236, COSV50659658; called by muse, mutect2, varscan2
- PCLO | c.12881G>C p.R4294T | Missense Mutation (SNP) | VAF 81/224 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61632311; called by muse, mutect2, varscan2
- PDZD11 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV52103879, COSV99333463; called by muse, mutect2, varscan2
- PODN | c.1432C>T p.R478C (on ENST00000395871; = p.R430C on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/503 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as rs551408418, COSV57015173; called by muse, mutect2, varscan2
- SCN9A | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 166/325 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV57605175, COSV57626144; called by muse, mutect2, varscan2
- SERPINA9 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 115/378 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs768085902; called by muse, mutect2, varscan2
- SHC2 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 70/135 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1238411807; called by muse, mutect2, varscan2
- SHC4 | c.1789C>T p.H597Y | Missense Mutation (SNP) | VAF 113/284 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100194398; called by muse, mutect2, varscan2
- SIRPB1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 59/470 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs145431656; called by muse, mutect2, varscan2
- SLC1A7 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs780578218; called by muse, mutect2, varscan2
- SLC22A6 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 139/289 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs745391498; called by muse, mutect2, varscan2
- SVEP1 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100237283; called by muse, mutect2
- TMEM31 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 86/455 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.209); catalogued as COSV60327306; called by muse, mutect2, varscan2
- TOX3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 112/240 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748115079; called by muse, mutect2, varscan2
- TTC8 | c.1177G>A p.D393N (on ENST00000338104 / NM_001288781.1; = p.D377N on NM_144596.4) | Missense Mutation (SNP) | VAF 136/452 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752893116; called by muse, mutect2, varscan2
- TTN | c.8664G>A p.M2888I (on ENST00000591111; = p.M2842I on NM_003319.4) | Missense Mutation (SNP) | VAF 70/165 reads (42%) | PolyPhen benign (0.269); catalogued as rs866436178, COSV59906768, COSV60358844; called by muse, mutect2, varscan2
- WDR87 | c.5323G>A p.E1775K | Missense Mutation (SNP) | VAF 172/381 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV58198143; called by muse, mutect2, varscan2
- AGBL1 | c.1735A>T p.S579C | Missense Mutation (SNP) | VAF 93/236 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBA1 | c.1746A>T p.K582N | Missense Mutation (SNP) | VAF 190/439 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- ARNT2 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 120/280 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.822); called by muse, varscan2
- BCLAF3 | c.202A>T p.N68Y | Missense Mutation (SNP) | VAF 98/676 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CCDC177 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 259/817 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CDH23 | c.4160T>G p.L1387W | Missense Mutation (SNP) | VAF 190/377 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLDN8 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 195/506 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN1 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- COL6A1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 119/442 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX18 | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 114/271 reads (42%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPN2 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 136/508 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- FAT4 | c.9958G>A p.G3320R | Missense Mutation (SNP) | VAF 115/375 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA3 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 120/459 reads (26%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRAMD1C | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 125/301 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- IL1RAPL1 | c.255T>G p.F85L | Missense Mutation (SNP) | VAF 182/539 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNA3 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 155/355 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LBX1 | c.508A>C p.I170L | Missense Mutation (SNP) | VAF 135/351 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LY6D | c.269A>T p.D90V | Missense Mutation (SNP) | VAF 196/450 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCOL | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 109/241 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- MAST2 | c.2759C>T p.S920L | Missense Mutation (SNP) | VAF 53/352 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- MSH3 | c.1631A>G p.N544S | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC4 | c.2360C>T p.T787I | Missense Mutation (SNP) | VAF 85/669 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- NCAN | c.3802C>T p.Q1268* | Nonsense Mutation (SNP) | VAF 112/272 reads (41%) | called by muse, mutect2, varscan2
- NOTO | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 30/534 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- OR10H5 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 262/610 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2
- PHF8 | c.2974G>A p.A992T (on ENST00000357988 / NM_001184896.1; = p.A956T on NM_015107.3) | Missense Mutation (SNP) | VAF 36/760 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); called by muse, mutect2
- PKHD1L1 | c.6410C>A p.S2137Y | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- PLXNA2 | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 153/384 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PPFIA2 | c.3551A>T p.D1184V | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PRAMEF19 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 108/247 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- RBMXL2 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 166/427 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- RFPL4AL1 | c.856G>C p.G286R | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.196); called by muse, varscan2
- RIPPLY2 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 168/620 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- SAGE1 | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 79/373 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SATL1 | c.1A>C p.M1? (on ENST00000395409; = p.M188L on NM_001012980.2) | Translation Start Site (SNP) | VAF 231/620 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SCARA3 | c.659T>G p.V220G | Missense Mutation (SNP) | VAF 162/369 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SCLT1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 116/422 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMG1 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCA4 | c.3716C>T p.S1239F | Missense Mutation (SNP) | VAF 172/355 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- TENM1 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 115/501 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- TES | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 95/239 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- TNPO1 | c.1215T>A p.H405Q | Missense Mutation (SNP) | VAF 90/241 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTN | c.10636dup p.S3546Ffs*3 (on ENST00000591111; = p.S3500Ffs*3 on NM_003319.4) | Frame Shift Ins (INS) | VAF 134/316 reads (42%) | called by mutect2, pindel, varscan2
- TXNDC16 | c.863G>T p.R288I | Missense Mutation (SNP) | VAF 114/371 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.114); called by mutect2, varscan2
- UNCX | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- USP17L7 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 151/656 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- VCAN | c.8953G>A p.G2985R | Missense Mutation (SNP) | VAF 168/343 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- WASF3 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 139/374 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ZNF492 | c.1133C>G p.S378* | Nonsense Mutation (SNP) | VAF 92/241 reads (38%) | called by muse, mutect2, varscan2
- ADGRG1 | c.873G>A p.V291= | Silent (SNP) | VAF 99/226 reads (44%) | catalogued as rs1013551049; called by muse, mutect2, varscan2
- BEX5 | c.240G>A p.R80= | Silent (SNP) | VAF 184/557 reads (33%) | catalogued as COSV61328467; called by muse, mutect2, varscan2
- BNC2 | c.2211C>T p.S737= | Silent (SNP) | VAF 161/384 reads (42%) | called by muse, mutect2, varscan2
- C18orf63 | c.1974T>C p.Y658= | Silent (SNP) | VAF 35/207 reads (17%) | called by muse, mutect2, varscan2
- CCN1 | c.327C>T p.N109= | Silent (SNP) | VAF 115/251 reads (46%) | called by muse, mutect2, varscan2
- CLRN2 | c.504C>T p.I168= | Silent (SNP) | VAF 56/620 reads (9%) | catalogued as rs985446427, COSV101492688, COSV71825214; called by muse, mutect2
- COBL | c.336C>T p.T112= | Silent (SNP) | VAF 124/298 reads (42%) | catalogued as COSV54336841; called by muse, mutect2, varscan2
- CREBBP | c.4614C>T p.P1538= | Silent (SNP) | VAF 139/353 reads (39%) | catalogued as rs1017285045; called by muse, mutect2, varscan2
- CSN2 | c.192G>C p.L64= | Silent (SNP) | VAF 115/374 reads (31%) | called by muse, mutect2, varscan2
- CYP7B1 | c.288C>T p.P96= | Silent (SNP) | VAF 60/148 reads (41%) | called by muse, mutect2, varscan2
- DENND2A | c.1746C>T p.Y582= | Silent (SNP) | VAF 137/263 reads (52%) | catalogued as rs561524063, COSV52056442; called by muse, mutect2, varscan2
- DENND2C | c.447G>T p.L149= | Silent (SNP) | VAF 12/276 reads (4%) | called by muse, mutect2
- DOLK | c.558C>T p.P186= | Silent (SNP) | VAF 127/317 reads (40%) | catalogued as rs778566642; called by muse, mutect2, varscan2
- DST | c.19782G>A p.R6594= (on ENST00000361203 / NM_001374722.1; = p.R4291= on NM_015548.5) | Silent (SNP) | VAF 62/197 reads (31%) | called by muse, mutect2, varscan2
- FAM135B | c.1254G>A p.A418= | Silent (SNP) | VAF 91/196 reads (46%) | catalogued as rs746092198, COSV99419116; called by muse, mutect2, varscan2
- FASN | c.2796C>T p.S932= | Silent (SNP) | VAF 91/338 reads (27%) | catalogued as rs770009057, COSV60757437; called by muse, mutect2, varscan2
- FIS1 | c.114C>T p.Y38= | Silent (SNP) | VAF 159/344 reads (46%) | catalogued as rs766731863, COSV56191748; called by muse, mutect2, varscan2
- GABRG1 | c.966G>A p.K322= | Silent (SNP) | VAF 79/316 reads (25%) | called by muse, mutect2, varscan2
- HOXA13 | c.417C>T p.P139= | Silent (SNP) | VAF 223/488 reads (46%) | called by muse, mutect2, varscan2
- HSPG2 | c.11943C>T p.S3981= | Silent (SNP) | VAF 170/370 reads (46%) | catalogued as COSV60829114; called by muse, varscan2
- IRS4 | c.366C>T p.V122= | Silent (SNP) | VAF 166/637 reads (26%) | called by muse, mutect2, varscan2
- MAGEB18 | c.366T>C p.Y122= | Silent (SNP) | VAF 117/671 reads (17%) | called by muse, mutect2, varscan2
- OBSL1 | c.3750C>T p.A1250= | Silent (SNP) | VAF 170/368 reads (46%) | called by muse, mutect2, varscan2
- RNASE11 | c.381G>A p.V127= | Silent (SNP) | VAF 119/410 reads (29%) | called by muse, mutect2, varscan2
- SLC1A7 | c.1026C>T p.S342= | Silent (SNP) | VAF 74/169 reads (44%) | called by muse, mutect2, varscan2
- SMARCA4 | c.3717C>T p.S1239= | Silent (SNP) | VAF 172/353 reads (49%) | catalogued as rs746733739; ClinVar: likely benign; called by muse, mutect2, varscan2
- SORBS2 | c.1605C>T p.T535= | Silent (SNP) | VAF 134/467 reads (29%) | catalogued as rs145496396; called by muse, mutect2, varscan2
- TNNI3 | c.192G>A p.E64= | Silent (SNP) | VAF 160/396 reads (40%) | called by muse, mutect2
- TNXB | c.8772C>T p.H2924= (on ENST00000647633; = p.H2677= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 208/727 reads (29%) | catalogued as rs777770266, COSV100926576; called by muse, mutect2, varscan2
- WWC2 | c.1275A>C p.S425= | Silent (SNP) | VAF 55/289 reads (19%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*2281C>T | 3'UTR (SNP) | VAF 110/268 reads (41%) | catalogued as rs199563006, COSV57076029; called by muse, mutect2, varscan2
- GLUL | c.-17T>A | 5'UTR (SNP) | VAF 69/174 reads (40%) | called by muse, mutect2, varscan2
- NSUN4 | c.94-1375T>G | Intron (SNP) | VAF 125/246 reads (51%) | called by muse, mutect2, varscan2
- PAX4 | c.145-47C>T | Intron (SNP) | VAF 146/349 reads (42%) | catalogued as rs777573970; called by muse, mutect2, varscan2
- PKD1L2 | n.2975C>T | RNA (SNP) | VAF 160/388 reads (41%) | catalogued as rs1417346720; called by muse, mutect2, varscan2
- PNCK | chrX:153674018 C>T | 5'Flank (SNP) | VAF 230/657 reads (35%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2758-1884G>A | Intron (SNP) | VAF 54/140 reads (39%) | called by muse, mutect2, varscan2
- SUMO3 | c.150+17C>T | Intron (SNP) | VAF 206/662 reads (31%) | catalogued as rs1251326759; called by muse, mutect2, varscan2
